Somatic mutation profile of tumor specimen TCGA-76-4931-01A (aliquot TCGA-76-4931-01A-01D-1486-08) from TCGA case TCGA-76-4931, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.7 years (25,812 days).
Specimen TCGA-76-4931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc555163-c195-4507-9eeb-f2cc3f9a6ad6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4931-10A (Blood Derived Normal), aliquot TCGA-76-4931-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ef6378-0647-4574-a255-600e7355e402

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 27, Silent 14, Nonsense Mutation 5, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 3004/3173 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 117/151 reads (77%) | catalogued as rs765433422, COSV64294737, COSV99057830; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.47086C>T p.R15696* (on ENST00000591111; = p.R8272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/62 reads (61%) | catalogued as rs1343120755, COSV100624672, COSV59893970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs199640938, COSV60253696; called by muse, mutect2, varscan2
- AHNAK2 | c.6650T>G p.V2217G | Missense Mutation (SNP) | VAF 124/251 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV60926689; called by muse, mutect2, varscan2
- ASB9 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 73/177 reads (41%) | catalogued as COSV66852205; called by muse, mutect2, varscan2
- ATP2A1 | c.2959G>A p.V987I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs200445830, COSV62870658; called by muse, mutect2, varscan2
- AVPR1A | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs748353963, COSV54547767; called by muse, mutect2, varscan2
- CARD11 | c.383C>G p.T128R | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62717090, COSV62719204; called by muse, mutect2, varscan2
- CCDC157 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs971003042, COSV57841659; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CEP250 | c.6091C>G p.L2031V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61173390; called by muse, mutect2, varscan2
- CHRNB2 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV63809201; called by muse, mutect2, varscan2
- DENND1C | c.1148T>G p.L383R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67374848; called by muse, varscan2
- DNAH2 | c.10810C>T p.R3604W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs202094383; called by muse, mutect2
- GABRA6 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376700482, COSV50882721; called by muse, mutect2, varscan2
- GCNA | c.1686G>A p.M562I | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV65467884; called by muse, mutect2, varscan2
- GCSAML | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63579124, COSV63579337; called by muse, mutect2, varscan2
- GPR12 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753635977, COSV67344437; called by muse, mutect2, varscan2
- HCFC1 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV60076424; called by muse, mutect2, varscan2
- LMX1B | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV62741349; called by muse, mutect2, varscan2
- MFNG | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV52659354; called by muse, mutect2, varscan2
- MKRN3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV58809790, COSV58811645; called by muse, mutect2, varscan2
- NEO1 | c.2684G>A p.W895* | Nonsense Mutation (SNP) | VAF 57/129 reads (44%) | catalogued as COSV56076855; called by muse, mutect2, varscan2
- NOMO1 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as rs777784668, COSV55060827; called by muse, mutect2, varscan2
- NOS1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs764344401, COSV100500499, COSV57611683, COSV57620123; called by muse, mutect2, varscan2
- OR2A1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753997832, COSV68822970; called by muse, mutect2, varscan2
- OR6C6 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs77411445; called by muse, mutect2, varscan2
- PPIAL4A | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 161/415 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1270510528; called by muse, mutect2, varscan2
- PRPF19 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as rs1017944175, COSV57128999; called by muse, mutect2, varscan2
- SCNN1B | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373232226; called by muse, mutect2, varscan2
- XDH | c.3083G>A p.G1028D | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65150738; called by muse, mutect2, varscan2
- ZFP42 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200711766, COSV58816789; called by muse, mutect2, varscan2
- ADAM2 | c.1626C>T p.C542= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as rs201864039, COSV55866929, COSV99696491; called by muse, mutect2, varscan2
- COMP | c.357G>A p.T119= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs775643921, COSV99721490; called by muse, varscan2
- DNMT3A | c.1074G>A p.T358= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs200905691, COSV53079760; called by muse, mutect2, varscan2
- EMILIN1 | c.1560G>A p.T520= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs373844330, COSV99566325; called by muse, varscan2
- GRIN3B | c.1785C>T p.Y595= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as rs770764248, COSV52260939; called by muse, mutect2, varscan2
- GYG2 | c.1356C>T p.A452= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV58551378; called by muse, mutect2, varscan2
- HEPHL1 | c.312G>A p.L104= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV59889375; called by muse, mutect2, varscan2
- MICALL2 | c.675G>A p.G225= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs200801518, COSV52518048; called by muse, mutect2, varscan2
- PIK3CG | c.426G>A p.P142= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs747872159, COSV63248555; called by muse, mutect2, varscan2
- SERTAD2 | c.312G>A p.P104= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs201985620, COSV57641030; called by muse, mutect2, varscan2
- SMC3 | c.1710G>A p.T570= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as rs1391232237, COSV62421803; called by muse, mutect2, varscan2
- SUSD2 | c.411C>T p.S137= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs1234091183, COSV54087545; called by muse, mutect2, varscan2
- TRIM44 | c.807G>A p.V269= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as COSV54986752; called by muse, mutect2, varscan2
- ZP4 | c.720T>C p.T240= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as rs776875123, COSV63911170, COSV63913189; called by muse, mutect2, varscan2
